Somatic mutation profile of tumor specimen TCGA-44-A4SS-01A (aliquot TCGA-44-A4SS-01A-11D-A24P-08) from TCGA case TCGA-44-A4SS, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 73.9 years (26,991 days).
Specimen TCGA-44-A4SS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 22e9286d-c0d8-443e-8de8-65fbcf4903cd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-44-A4SS-10A (Blood Derived Normal), aliquot TCGA-44-A4SS-10A-01D-A24P-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a73e30b7-55b7-4465-9132-4bfadfcaf372

The open-access MAF lists 505 somatic variants for this specimen: 389 protein-altering or splice-affecting, 104 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 332, Silent 104, Nonsense Mutation 28, Splice Site 12, Frame Shift Del 11, Intron 7, RNA 3, Frame Shift Ins 2, Splice Region 2, 3'Flank 1, Nonstop Mutation 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NUP93 | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 11/91 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as rs528073782, COSV57428317; called by muse, mutect2, varscan2
- TP53 | c.734G>T p.G245V | Missense Mutation (SNP) | VAF 13/64 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121912656, CM010464, CM900209, COSV52666323, COSV52667838, COSV52745465; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.733G>T p.G245C | Missense Mutation (SNP) | VAF 13/64 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA4 | c.1038G>T p.K346N | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.211); catalogued as CD011578, COSV100933052; called by muse, mutect2, varscan2
- ACAP2 | c.1729C>A p.P577T | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV100461626; called by muse, mutect2
- ACBD5 | c.1315A>T p.R439* (on ENST00000375888 / NM_001352568.1; = p.R430* on NM_145698.5 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 24/146 reads (16%) | catalogued as COSV101022504; called by muse, mutect2, varscan2
- ACD | c.130G>T p.G44C | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.339); catalogued as COSV99537499; called by muse, mutect2, varscan2
- ACP7 | c.808-2A>T p.X270_splice | Splice Site (SNP) | VAF 14/140 reads (10%) | catalogued as COSV100488440; called by muse, mutect2, varscan2
- ADAM19 | c.962C>A p.S321Y | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99976390; called by muse, mutect2, varscan2
- ADAM2 | c.883G>T p.V295F | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV99696909; called by muse, mutect2, varscan2
- ADAMTS12 | c.3788C>A p.T1263K | Missense Mutation (SNP) | VAF 50/291 reads (17%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV100710420, COSV61263698; called by muse, mutect2, varscan2
- ADAMTS15 | c.2508C>G p.D836E | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT tolerated (0.98); PolyPhen benign (0.019); catalogued as COSV100143159, COSV100143815, COSV54508352; called by muse, mutect2, varscan2
- ADCY2 | c.1596G>C p.Q532H | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.652); catalogued as COSV100602058; called by muse, mutect2, varscan2
- AKAP17A | c.649G>C p.A217P | Missense Mutation (SNP) | VAF 25/201 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100001955; called by muse, mutect2
- AKAP3 | c.668G>A p.S223N | Missense Mutation (SNP) | VAF 8/173 reads (5%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.583); catalogued as COSV99961867; called by muse, mutect2
- ALDH1L1 | c.389G>T p.G130V | Missense Mutation (SNP) | VAF 6/144 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.61); catalogued as COSV56418009; called by muse, mutect2
- ALDOB | c.742C>A p.Q248K | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV100878826; called by muse, mutect2, varscan2
- ALG11 | c.500G>T p.C167F | Missense Mutation (SNP) | VAF 15/152 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101584258; called by muse, mutect2, varscan2
- AMN1 | c.608A>G p.H203R | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV99861446; called by muse, mutect2
- AMY2A | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 16/218 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.654); catalogued as COSV70215142; called by muse, mutect2
- ANO2 | c.1654G>A p.V552M (on ENST00000356134 / NM_001278597.3; = p.V556M on NM_001278596.3) | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV100500052; called by muse, mutect2, varscan2
- ANO7 | c.2800T>C p.*934Rext*207 (on ENST00000274979; = p.*880Rext*207 on NM_001370694.2) | Nonstop Mutation (SNP) | VAF 6/48 reads (13%) | catalogued as rs1362404258; called by mutect2, varscan2
- AP1G1 | c.1654G>T p.G552* | Nonsense Mutation (SNP) | VAF 12/76 reads (16%) | catalogued as COSV100250125, COSV55488126; called by muse, mutect2, varscan2
- AP1G1 | c.1124G>T p.G375V | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.03); catalogued as COSV100250128; called by muse, mutect2, varscan2
- AP1G1 | c.1123G>T p.G375W | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV100250131; called by muse, mutect2, varscan2
- APC | c.6878G>T p.G2293V | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs1299914025, COSV99965961; called by muse, mutect2, varscan2
- APOA4 | c.119A>T p.N40I | Missense Mutation (SNP) | VAF 33/213 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100759265; called by muse, mutect2, varscan2
- AQR | c.3644G>T p.C1215F | Missense Mutation (SNP) | VAF 7/101 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.638); catalogued as COSV99333397; called by muse, mutect2
- ARFGAP1 | c.1101G>T p.W367C | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100796643; called by muse, mutect2, varscan2
- ARHGAP18 | c.1877dup p.L626Ffs*3 | Frame Shift Ins (INS) | VAF 10/58 reads (17%) | catalogued as rs866380047; called by mutect2, varscan2
- ATP2B2 | c.651A>C p.K217N | Missense Mutation (SNP) | VAF 34/204 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV100659777; called by muse, mutect2, varscan2
- ATP4A | c.966G>A p.M322I | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.02); catalogued as rs1395233145, COSV99382251; called by muse, mutect2
- ATRX | c.3916C>A p.Q1306K | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.014); catalogued as COSV100970218; called by muse, mutect2, varscan2
- BAK1 | c.145G>T p.A49S | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as COSV100645831; called by muse, mutect2, varscan2
- BCAS1 | c.414G>T p.W138C | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.438); catalogued as COSV101006047; called by muse, mutect2, varscan2
- BCHE | c.804G>T p.R268S | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV100012219, COSV52254191; called by muse, mutect2, varscan2
- BCL2L14 | c.562T>G p.F188V | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV99844905; called by muse, mutect2
- BCL3 | c.1360A>T p.S454C | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV99378008; called by muse, mutect2, varscan2
- CACNA1F | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100544478, COSV59906936; called by muse, mutect2, varscan2
- CARD8 | c.1045G>T p.D349Y (on ENST00000651546 / NM_001184900.3; = p.D299Y on NM_014959.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100751024; called by muse, mutect2
- CCDC170 | c.2119C>A p.P707T | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as COSV99498212; called by muse, mutect2, varscan2
- CCDC34 | c.470G>T p.R157L | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100156444; called by muse, varscan2
- CD109 | c.1126G>C p.D376H | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99752860; called by muse, mutect2
- CD1C | c.281G>C p.G94A | Missense Mutation (SNP) | VAF 30/143 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as COSV100939360; called by muse, mutect2, varscan2
- CD200R1L | c.561G>A p.W187* | Nonsense Mutation (SNP) | VAF 13/48 reads (27%) | catalogued as COSV101236556, COSV101236583; called by muse, mutect2, varscan2
- CDC73 | c.922A>G p.K308E | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); catalogued as COSV100813734; called by muse, mutect2, varscan2
- CDH10 | c.1198G>T p.G400C | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV52593849; called by muse, varscan2
- CDH18 | c.748G>T p.G250* | Nonsense Mutation (SNP) | VAF 5/68 reads (7%) | catalogued as COSV99932746; called by muse, mutect2
- CDH8 | c.1944A>C p.K648N | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV100179998, COSV100184081; called by mutect2, varscan2
- CDKL4 | c.736-2A>G p.X246_splice | Splice Site (SNP) | VAF 5/37 reads (14%) | catalogued as rs1486697880, COSV101115145; called by muse, mutect2
- CELF3 | c.349C>A p.P117T | Missense Mutation (SNP) | VAF 14/314 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as COSV99310091; called by muse, mutect2
- CELF5 | c.707C>G p.S236C | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.593); catalogued as COSV99485757; called by muse, mutect2, varscan2
- CELSR2 | c.5205T>A p.H1735Q | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.342); catalogued as COSV99603260; called by muse, mutect2, varscan2
- CELSR2 | c.5206G>T p.G1736C | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99603262; called by muse, mutect2, varscan2
- CENPF | c.263A>T p.H88L | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100871548; called by muse, mutect2, varscan2
- CEP152 | c.1956A>C p.L652F | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100358587; called by muse, mutect2, varscan2
- CGB7 | c.433C>T p.P145S | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs141827342, COSV100655013, COSV62281855; called by muse, mutect2, varscan2
- CHD6 | c.2378C>G p.P793R | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV100497894; called by muse, mutect2, varscan2
- CHPF2 | c.1495G>A p.E499K | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.461); catalogued as COSV99222875; called by muse, mutect2, varscan2
- CHRDL2 | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.075); catalogued as COSV99733608; called by muse, mutect2
- CLCN1 | c.2844G>T p.E948D | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0.046); catalogued as COSV100577785; called by muse, mutect2, varscan2
- CLDN25 | c.129G>T p.M43I | Missense Mutation (SNP) | VAF 21/156 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.173); catalogued as COSV101493582; called by muse, mutect2, varscan2
- CLEC10A | c.205C>A p.L69M | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.981); catalogued as COSV99644578; called by muse, mutect2, varscan2
- CLHC1 | c.121A>C p.S41R | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV101284851; called by muse, mutect2, varscan2
- CLN8 | c.22G>C p.G8R | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT tolerated (0.53); PolyPhen benign (0.037); catalogued as COSV100485992; called by muse, mutect2
- CLPTM1 | c.439G>T p.E147* | Nonsense Mutation (SNP) | VAF 14/96 reads (15%) | catalogued as COSV100493663; called by muse, mutect2, varscan2
- CNTNAP4 | c.1881C>G p.T627= | Splice Region (SNP) | VAF 23/132 reads (17%) | catalogued as rs374622637, COSV100269834, COSV56685383; called by muse, mutect2, varscan2
- COBL | c.1111G>T p.G371W | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.066); catalogued as COSV54337423, COSV99471639; called by muse, mutect2, varscan2
- COL1A2 | c.692C>T p.A231V | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV99798852; called by muse, mutect2, varscan2
- COL1A2 | c.3544C>A p.P1182T | Missense Mutation (SNP) | VAF 26/229 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51965713, COSV99798854; called by muse, mutect2, varscan2
- COL22A1 | c.1568C>A p.P523H | Missense Mutation (SNP) | VAF 14/234 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.657); catalogued as rs1253727568, COSV100276845, COSV57352240; called by muse, mutect2
- COLEC11 | c.108G>T p.Q36H | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0.024); catalogued as COSV99362931; called by muse, mutect2, varscan2
- CPN1 | c.593G>T p.R198L | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs374397752, COSV100962568, COSV64942136; called by muse, mutect2, varscan2
- CPQ | c.29G>T p.G10V | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.003); catalogued as COSV99610940; called by muse, mutect2, varscan2
- CRABP2 | c.287G>C p.C96S | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV63959003, COSV63959173; called by muse, mutect2, varscan2
- CSF1R | c.1719G>C p.E573D | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.114); catalogued as COSV99641113; called by muse, mutect2, varscan2
- CSTF2 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.114); catalogued as COSV100802922, COSV100802967; called by muse, mutect2, varscan2
- CYP26B1 | c.451C>T p.H151Y | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.246); catalogued as COSV99134318; called by muse, mutect2, varscan2
- CYP39A1 | c.493C>A p.L165I | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0.051); catalogued as COSV99241954; called by muse, mutect2, varscan2
- CYRIB | c.695G>C p.R232T | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.744); catalogued as COSV101309758; called by muse, mutect2, varscan2
- DAB2 | c.787T>A p.C263S | Missense Mutation (SNP) | VAF 17/156 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100297830; called by muse, mutect2, varscan2
- DACH2 | c.1352G>T p.S451I | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as COSV100912689; called by muse, mutect2
- DCDC1 | c.4396C>A p.R1466S (on ENST00000597505 / NM_001367979.1; = p.R573S on NM_020869.3) | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.74); PolyPhen benign (0.099); catalogued as COSV100337933, COSV100338441, COSV57998997; called by muse, mutect2, varscan2
- DDX6 | c.517A>G p.T173A | Missense Mutation (SNP) | VAF 48/306 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.489); catalogued as COSV99870154; called by muse, mutect2, varscan2
- DMD | c.4604C>T p.T1535M | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1431604157, COSV100822817, COSV63771742; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAJB8 | c.236C>A p.A79D | Missense Mutation (SNP) | VAF 12/161 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV100048147; called by muse, mutect2
- DNAJC27 | c.391G>T p.V131F | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99266473; called by muse, mutect2, varscan2
- DOCK8 | c.5135C>G p.P1712R | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.762); catalogued as COSV101209834; called by muse, mutect2, varscan2
- DPH2 | c.794G>C p.G265A | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.138); catalogued as COSV99356278; called by muse, mutect2
- DSC3 | c.138C>A p.D46E | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100844551; called by muse, mutect2, varscan2
- DSCAM | c.1616A>G p.K539R | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.306); catalogued as COSV101259364; called by muse, mutect2, varscan2
- DSCAML1 | c.1616A>G p.D539G (on ENST00000321322; = p.D479G on NM_020693.4) | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1382110333, COSV100355003; called by muse, mutect2, varscan2
- ELAPOR1 | c.1600A>G p.K534E | Missense Mutation (SNP) | VAF 14/208 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100884414; called by muse, mutect2
- ELAVL2 | c.506G>T p.G169V | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99805615; called by muse, mutect2, varscan2
- EPG5 | c.5359A>T p.R1787W | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV99956687; called by muse, mutect2
- EPHA3 | c.1490G>T p.S497I | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.697); catalogued as COSV100343615; called by muse, mutect2, varscan2
- EPHA5 | c.559G>C p.D187H | Missense Mutation (SNP) | VAF 13/173 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99896984, COSV99899299; called by muse, mutect2
- ERCC4 | c.487G>A p.A163T | Missense Mutation (SNP) | VAF 32/167 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs778574449, COSV100318731; called by muse, mutect2, varscan2
- ERICH3 | c.3975C>A p.N1325K | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT tolerated (0.88); PolyPhen benign (0.048); catalogued as COSV100443656; called by muse, mutect2, varscan2
- ETS1 | c.343G>C p.E115Q | Missense Mutation (SNP) | VAF 19/223 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.194); catalogued as COSV100090197; called by muse, mutect2
- EXPH5 | c.5915C>A p.T1972K | Missense Mutation (SNP) | VAF 30/235 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99761127; called by muse, mutect2, varscan2
- F2R | c.613G>T p.V205L | Missense Mutation (SNP) | VAF 35/184 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.136); catalogued as COSV100058360; called by muse, mutect2, varscan2
- FAM135B | c.1441G>T p.E481* | Nonsense Mutation (SNP) | VAF 13/108 reads (12%) | catalogued as COSV52705894, COSV52749033; called by muse, mutect2, varscan2
- FAM81B | c.1102C>G p.Q368E | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs756787447, COSV51981394; called by muse, mutect2, varscan2
- FBN1 | c.7960T>C p.S2654P | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.989); catalogued as COSV100354166; called by muse, mutect2
- FERD3L | c.269G>T p.G90V | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.035); catalogued as COSV99284765; called by muse, mutect2
- FGD5 | c.1300G>T p.V434L | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.978); catalogued as COSV99547507; called by muse, mutect2
- FKBP9 | c.330G>C p.K110N | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.189); catalogued as COSV99639104; called by muse, mutect2, varscan2
- FOXC2 | c.234C>G p.I78M | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100234140; called by muse, mutect2, varscan2
- FOXF2 | c.571C>T p.R191C | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52527443; called by muse, mutect2, varscan2
- FOXG1 | c.1462A>G p.I488V | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.14); catalogued as COSV100486590; called by muse, mutect2, varscan2
- FOXO1 | c.753G>T p.R251S | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101091840, COSV99058978; called by muse, mutect2, varscan2
- FSD1 | c.1009C>A p.R337S | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55695204, COSV99696636; called by muse, mutect2, varscan2
- G6PC2 | c.462G>C p.W154C | Missense Mutation (SNP) | VAF 18/175 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56373615; called by muse, mutect2, varscan2
- GADD45GIP1 | c.464G>T p.R155L | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.374); catalogued as rs754680189, COSV100379941; called by muse, mutect2, varscan2
- GASK1B | c.138C>G p.I46M | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.684); catalogued as COSV99647394; called by muse, mutect2, varscan2
- GCKR | c.1678C>G p.H560D | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV99268826; called by muse, mutect2, varscan2
- GDA | c.646C>T p.L216F | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.947); catalogued as COSV99031740, COSV99428861; called by muse, mutect2, varscan2
- GDF9 | c.287A>G p.Y96C | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.043); catalogued as COSV99737164; called by muse, mutect2, varscan2
- GIMAP6 | c.133C>G p.L45V | Missense Mutation (SNP) | VAF 38/456 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100188126; called by muse, mutect2
- GLRA3 | c.267+2T>C p.X89_splice | Splice Site (SNP) | VAF 9/116 reads (8%) | catalogued as rs1261707734, COSV99927154; called by muse, mutect2
- GNL3L | c.449G>C p.C150S | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.168); catalogued as COSV100328185; called by muse, mutect2
- GPAT4 | c.611G>T p.R204M | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.147); catalogued as COSV101213895; called by muse, mutect2, varscan2
- GPC3 | c.977C>A p.T326K | Missense Mutation (SNP) | VAF 35/128 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV100892824; called by muse, mutect2, varscan2
- GPM6A | c.323G>T p.G108V | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99703003; called by muse, mutect2
- GPR149 | c.518G>T p.G173V | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV101078191; called by muse, mutect2, varscan2
- GPR37 | c.380G>T p.G127V | Missense Mutation (SNP) | VAF 27/160 reads (17%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV100390601; called by muse, mutect2, varscan2
- GPRC6A | c.252C>G p.I84M | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.942); catalogued as COSV100114120; called by muse, mutect2, varscan2
- GREB1 | c.3323-1G>T p.X1108_splice | Splice Site (SNP) | VAF 42/343 reads (12%) | catalogued as COSV99302372; called by muse, mutect2, varscan2
- GRIN2B | c.2438T>A p.L813Q | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101662944; called by muse, mutect2, varscan2
- GSPT2 | c.1561A>G p.T521A | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.448); catalogued as COSV100467981; called by muse, mutect2, varscan2
- H4C5 | c.52C>G p.R18G | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT deleterious (0.01); catalogued as COSV100747890; called by muse, mutect2, varscan2
- HELZ | c.3424C>T p.Q1142* | Nonsense Mutation (SNP) | VAF 12/110 reads (11%) | catalogued as COSV100698552; called by muse, mutect2
- HERC1 | c.7268A>T p.E2423V | Missense Mutation (SNP) | VAF 13/148 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.056); catalogued as COSV101496399; called by muse, mutect2
- HHLA2 | c.254A>G p.D85G | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.062); catalogued as COSV100755255; called by muse, mutect2, varscan2
- HMCN1 | c.4475+1G>T p.X1492_splice | Splice Site (SNP) | VAF 16/95 reads (17%) | catalogued as COSV99625413; called by muse, mutect2, varscan2
- HMCN1 | c.5147G>T p.S1716I | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV99625415; called by muse, mutect2, varscan2
- HMCN1 | c.15173C>A p.T5058K | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.738); catalogued as COSV99625423; called by muse, mutect2, varscan2
- HNRNPA3 | c.73-1G>T p.X25_splice | Splice Site (SNP) | VAF 23/123 reads (19%) | catalogued as COSV66821015; called by muse, mutect2, varscan2
- HNRNPF | c.203A>C p.K68T | Missense Mutation (SNP) | VAF 9/109 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.436); catalogued as rs772316006, COSV100562981; called by muse, mutect2
- HSD3B2 | c.214T>A p.C72S | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101027434; called by muse, mutect2, varscan2
- HSPA1L | c.1373T>A p.L458Q | Missense Mutation (SNP) | VAF 54/183 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100989343; called by muse, mutect2, varscan2
- HSPG2 | c.7282G>T p.G2428C | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.633); catalogued as COSV65976909; called by muse, mutect2
- HTR1F | c.708A>T p.K236N | Missense Mutation (SNP) | VAF 7/113 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV60389092; called by muse, mutect2
- HTR2B | c.853G>A p.D285N | Missense Mutation (SNP) | VAF 35/193 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as COSV99295190; called by muse, mutect2, varscan2
- IFI44L | c.307A>G p.T103A | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.54); PolyPhen benign (0.006); catalogued as rs1285694363, COSV100654916; called by muse, mutect2, varscan2
- IFNA16 | c.158T>A p.L53Q | Missense Mutation (SNP) | VAF 30/204 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV101207058; called by muse, mutect2, varscan2
- INSR | c.3397C>T p.L1133F | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.161); catalogued as COSV100251695; called by muse, mutect2, varscan2
- ITGAV | c.2326G>T p.G776* | Nonsense Mutation (SNP) | VAF 10/68 reads (15%) | catalogued as COSV99654398; called by muse, mutect2, varscan2
- ITGB2 | c.612C>A p.F204L | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as COSV100185693, COSV56610817; called by muse, mutect2
- KCNH5 | c.322T>C p.Y108H | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.022); catalogued as COSV100525658; called by muse, mutect2, varscan2
- KCNT2 | c.1996G>T p.E666* | Nonsense Mutation (SNP) | VAF 7/40 reads (18%) | catalogued as COSV99652145; called by muse, mutect2
- KCNT2 | c.507C>A p.N169K | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV99652148; called by muse, mutect2
- KCNU1 | c.2404C>A p.P802T | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.024); catalogued as COSV101299008, COSV67753627; called by muse, mutect2, varscan2
- KCTD3 | c.350G>T p.R117L | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); catalogued as COSV52067724, COSV99378967; called by muse, mutect2, varscan2
- KEL | c.2005C>A p.P669T | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.197); catalogued as rs751310423, COSV100786861, COSV100786913; called by muse, mutect2
- KIAA1549L | c.4732G>A p.A1578T (on ENST00000321505; = p.A1875T on NM_012194.3) | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV100381020; called by muse, mutect2, varscan2
- KIAA2026 | c.3346G>A p.E1116K | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.621); catalogued as COSV101198893; called by muse, mutect2
- KIF19 | c.42G>A p.V14= | Splice Region (SNP) | VAF 4/11 reads (36%) | catalogued as rs1182005574, COSV100738983; called by muse, mutect2
- KIF1A | c.3221T>A p.F1074Y | Missense Mutation (SNP) | VAF 41/177 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as COSV100240068; called by muse, mutect2, varscan2
- KIF26A | c.3599C>A p.A1200E | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.107); catalogued as COSV100180850; called by muse, mutect2
- KLHL36 | c.457G>T p.E153* | Nonsense Mutation (SNP) | VAF 21/111 reads (19%) | catalogued as COSV99077157; called by muse, mutect2, varscan2
- KLHL5 | c.578C>G p.S193* | Nonsense Mutation (SNP) | VAF 5/123 reads (4%) | catalogued as COSV99784936; called by muse, mutect2
- KMT2A | c.8422C>T p.R2808C | Missense Mutation (SNP) | VAF 12/224 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs782078199, COSV100628180; called by muse, mutect2
- KMT2E | c.3380A>G p.D1127G | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.321); catalogued as COSV99995943; called by muse, mutect2
- KRT76 | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.826); catalogued as COSV100195967; called by muse, mutect2
- L3MBTL3 | c.455A>G p.Q152R | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as COSV100695793; called by muse, mutect2, varscan2
- LAMA1 | c.8983G>T p.G2995W | Missense Mutation (SNP) | VAF 29/144 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101055403, COSV67535904; called by muse, mutect2, varscan2
- LAMA5 | c.7387G>T p.G2463W | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768563115, COSV99438523; called by muse, mutect2, varscan2
- LAMA5 | c.7105C>G p.Q2369E | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1468716486, COSV99438525; called by muse, mutect2, varscan2
- LAMA5 | c.5429G>T p.R1810M | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as rs1260516287, COSV99438197; called by muse, mutect2
- LOXL1 | c.1685G>A p.R562H | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.998); catalogued as rs557975431, COSV99985220; called by muse, varscan2
- LPCAT1 | c.449C>G p.S150C | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99358809; called by muse, mutect2, varscan2
- LRBA | c.4218T>A p.F1406L | Missense Mutation (SNP) | VAF 13/153 reads (8%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.97); catalogued as COSV100841073; called by muse, mutect2
- LRP1B | c.1181T>A p.V394E | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV101253885; called by muse, mutect2
- LRPPRC | c.3331A>C p.I1111L | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as rs781451529, COSV99580112; called by muse, mutect2, varscan2
- LRRC18 | c.770G>C p.R257P | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as COSV99628756, COSV99630821; called by muse, mutect2, varscan2
- LRRC7 | c.872A>G p.E291G (on ENST00000651989 / NM_001370785.2; = p.E258G on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.577); catalogued as COSV99225062; called by muse, mutect2, varscan2
- LRRIQ3 | c.1136del p.P379Lfs*26 | Frame Shift Del (DEL) | VAF 12/94 reads (13%) | catalogued as COSV63046007; called by mutect2, pindel, varscan2
- MAB21L1 | c.280C>A p.L94M | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.78); catalogued as COSV100077566, COSV59761496; called by muse, mutect2
- MACC1 | c.497A>G p.H166R | Missense Mutation (SNP) | VAF 25/140 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV100255538; called by muse, mutect2, varscan2
- MAGEC1 | c.3194C>A p.P1065H | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99595069; called by muse, mutect2, varscan2
- MAML3 | c.1125G>T p.Q375H | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100505029; called by muse, mutect2
- MANEA | c.493G>T p.D165Y | Missense Mutation (SNP) | VAF 34/147 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778603302, COSV100721463; called by muse, mutect2, varscan2
- MAPKAP1 | c.1486G>T p.D496Y (on ENST00000265960 / NM_001006617.3; = p.D460Y on NM_024117.3) | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV99784470; called by muse, mutect2, varscan2
- MAPKAPK3 | c.268C>G p.Q90E | Missense Mutation (SNP) | VAF 14/252 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.071); catalogued as COSV100781729; called by muse, mutect2
- MCOLN1 | c.1576-1G>T p.X526_splice | Splice Site (SNP) | VAF 4/25 reads (16%) | catalogued as COSV99653253; called by mutect2, varscan2
- MDN1 | c.3556C>T p.H1186Y | Missense Mutation (SNP) | VAF 54/206 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101020891; called by muse, mutect2, varscan2
- MEOX2 | c.829G>T p.A277S | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV100011975; called by muse, mutect2, varscan2
- MEOX2 | c.657G>C p.E219D | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1237411895, COSV100011977; called by muse, mutect2, varscan2
- MIGA1 | c.1564-2A>T p.X522_splice | Splice Site (SNP) | VAF 22/220 reads (10%) | catalogued as COSV100889750; called by muse, mutect2, varscan2
- MLXIPL | c.2522G>C p.R841P | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.774); catalogued as COSV100515204; called by muse, mutect2, varscan2
- MON2 | c.2383G>T p.V795F | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99741893; called by muse, mutect2
- MUC16 | c.28095G>A p.M9365I | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.005); catalogued as COSV101198642; called by muse, mutect2, varscan2
- MUC16 | c.16481C>A p.T5494K | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.238); catalogued as rs1002938332, COSV101198644; called by muse, mutect2, varscan2
- MXRA5 | c.2539C>A p.L847I | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV99476069; called by muse, mutect2, varscan2
- MYH2 | c.3970C>T p.Q1324* | Nonsense Mutation (SNP) | VAF 12/59 reads (20%) | catalogued as rs1567728744, COSV99819505; called by muse, mutect2, varscan2
- MYH2 | c.3969G>T p.R1323S | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.426); catalogued as COSV99819510; called by muse, mutect2, varscan2
- NARF | c.748G>T p.A250S | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.341); catalogued as COSV100559607; called by muse, mutect2, varscan2
- NCOA6 | c.1499G>T p.G500V | Missense Mutation (SNP) | VAF 34/156 reads (22%) | SIFT tolerated, low confidence (0.2); PolyPhen probably damaging (0.999); catalogued as COSV100749928; called by muse, mutect2, varscan2
- NELL1 | c.1549G>C p.A517P | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.624); catalogued as COSV100119567; called by muse, mutect2, varscan2
- NEPRO | c.210C>A p.Y70* | Nonsense Mutation (SNP) | VAF 10/91 reads (11%) | catalogued as COSV100074938; called by muse, mutect2, varscan2
- NETO1 | c.836G>A p.R279Q | Missense Mutation (SNP) | VAF 30/159 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.232); catalogued as rs1395330447, COSV55006087, COSV55012049; called by muse, mutect2, varscan2
- NFAT5 | c.2332C>G p.L778V | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100590568; called by muse, mutect2, varscan2
- NKRF | c.1780G>C p.D594H | Missense Mutation (SNP) | VAF 34/137 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.796); catalogued as COSV100441467; called by muse, mutect2, varscan2
- NLRP11 | c.2543T>A p.I848N | Missense Mutation (SNP) | VAF 18/173 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.379); catalogued as COSV100789655, COSV64088242; called by muse, mutect2, varscan2
- NPHP4 | c.1106G>T p.G369V | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs758027686, COSV100976757; called by muse, mutect2, varscan2
- NRXN1 | c.1040G>T p.G347V | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100453793, COSV58459204; called by muse, mutect2, varscan2
- NTNG1 | c.719T>C p.M240T | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV99635929; called by muse, mutect2, varscan2
- NTRK3 | c.1147C>G p.P383A | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as COSV100445929, COSV58110072; called by muse, mutect2, varscan2
- NUP155 | c.3043G>T p.E1015* (on ENST00000231498 / NM_153485.3; = p.E956* on NM_004298.4) | Nonsense Mutation (SNP) | VAF 16/194 reads (8%) | catalogued as COSV99192305; called by muse, mutect2
- NUP98 | c.1817A>G p.N606S | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.01); catalogued as rs371706295, COSV100263041; called by muse, mutect2, varscan2
- OR10G4 | c.382C>G p.P128A | Missense Mutation (SNP) | VAF 30/245 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.566); catalogued as COSV100304731; called by muse, mutect2, varscan2
- OR10J1 | c.473C>T p.T158M | Missense Mutation (SNP) | VAF 67/259 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.498); catalogued as rs772118508, COSV71128835; called by muse, mutect2, varscan2
- OR10W1 | c.25C>T p.P9S | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (1); PolyPhen possibly damaging (0.802); catalogued as COSV67720524, COSV67720616; called by muse, mutect2, varscan2
- OR2A25 | c.353C>A p.S118Y | Missense Mutation (SNP) | VAF 25/160 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1474313486, COSV101376355; called by muse, mutect2, varscan2
- OR2T33 | c.827A>T p.Y276F | Missense Mutation (SNP) | VAF 14/268 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100531697; called by muse, mutect2
- OR2T4 | c.680A>C p.Y227S | Missense Mutation (SNP) | VAF 28/237 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100822411; called by muse, mutect2, varscan2
- OR3A2 | c.224T>C p.L75P | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV101375043; called by muse, mutect2
- OR4A15 | c.694C>T p.R232* | Nonsense Mutation (SNP) | VAF 29/147 reads (20%) | catalogued as rs140143120, COSV59033884; called by muse, mutect2, varscan2
- OR4A47 | c.244G>A p.G82S | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs150210663, COSV71444861, COSV71445051; called by muse, mutect2, varscan2
- OR4D10 | c.887C>G p.S296* | Nonsense Mutation (SNP) | VAF 6/98 reads (6%) | catalogued as COSV101596999; called by muse, mutect2
- OR52I2 | c.578T>C p.V193A | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.458); catalogued as COSV100442855; called by muse, mutect2
- OR5D14 | c.321C>A p.C107* | Nonsense Mutation (SNP) | VAF 13/67 reads (19%) | catalogued as COSV100162212, COSV59456152; called by muse, mutect2
- OR6B2 | c.127C>A p.L43M | Missense Mutation (SNP) | VAF 16/215 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.051); catalogued as COSV53152837, COSV99401253; called by muse, mutect2
- OR6B3 | c.127C>A p.L43M | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.06); catalogued as COSV100097014; called by muse, mutect2, varscan2
- OR6C74 | c.903C>A p.H301Q | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.024); catalogued as COSV100667704; called by muse, mutect2
- OR6K2 | c.800A>T p.Y267F | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.074); catalogued as COSV100656724; called by muse, mutect2, varscan2
- OR7A5 | c.611C>A p.A204E | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.347); catalogued as COSV100457664, COSV59234008; called by muse, mutect2, varscan2
- OR7D4 | c.698G>T p.G233V | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV100432624; called by muse, mutect2, varscan2
- OR8D4 | c.316G>T p.V106F | Missense Mutation (SNP) | VAF 16/261 reads (6%) | SIFT tolerated (0.96); PolyPhen benign (0.001); catalogued as COSV100361720; called by muse, mutect2
- ORAI3 | c.647C>T p.S216F | Missense Mutation (SNP) | VAF 24/331 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.452); catalogued as COSV99352576; called by muse, mutect2
- OSBPL8 | c.2209C>G p.L737V | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV99674646; called by muse, mutect2
- OTP | c.368T>A p.F123Y | Missense Mutation (SNP) | VAF 33/175 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as COSV100119716; called by muse, mutect2, varscan2
- OVCH1 | c.100A>T p.S34C | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as COSV99758992; called by muse, mutect2, varscan2
- P2RY10 | c.943C>A p.Q315K | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as COSV99408978; called by muse, mutect2, varscan2
- PCDH17 | c.2657G>T p.S886I | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100931481; called by muse, mutect2, varscan2
- PCDHA1 | c.1838C>A p.P613Q | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.075); catalogued as rs782235113, COSV100974296; called by muse, mutect2, varscan2
- PCDHA2 | c.341T>A p.L114Q | Missense Mutation (SNP) | VAF 40/198 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV100973665; called by muse, mutect2, varscan2
- PCDHA3 | c.274C>T p.R92C | Missense Mutation (SNP) | VAF 20/276 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65367909, COSV65369850; called by muse, mutect2
- PCDHA8 | c.1556C>A p.A519E | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100969168, COSV65324408; called by muse, mutect2, varscan2
- PCDHB13 | c.2239C>G p.Q747E | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.271); catalogued as COSV99506906, COSV99507494; called by muse, mutect2
- PDHA2 | c.252C>A p.F84L | Missense Mutation (SNP) | VAF 13/133 reads (10%) | SIFT tolerated (0.65); PolyPhen benign (0.1); catalogued as COSV54779091, COSV99756593; called by muse, mutect2
- PDIA4 | c.1229A>G p.Y410C (on ENST00000286091 / NM_001371244.1; = p.Y409C on NM_004911.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1465431895, COSV99618343; called by muse, mutect2, varscan2
- PHF3 | c.1283C>G p.T428S | Missense Mutation (SNP) | VAF 30/182 reads (16%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100012990; called by muse, mutect2, varscan2
- PHF3 | c.2653T>A p.C885S | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as COSV100012994; called by muse, mutect2
- PIEZO2 | c.7420C>T p.Q2474* | Nonsense Mutation (SNP) | VAF 20/144 reads (14%) | catalogued as COSV99554597; called by muse, mutect2, varscan2
- PKD1L2 | c.172G>T p.G58W | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as COSV100449662; called by muse, mutect2
- PKHD1 | c.1510C>G p.Q504E | Missense Mutation (SNP) | VAF 27/133 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100581664; called by muse, mutect2, varscan2
- PKHD1L1 | c.8263G>A p.G2755R | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.119); catalogued as COSV101005600; called by muse, mutect2, varscan2
- PKP1 | c.2093C>T p.P698L | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV99824987; called by muse, mutect2, varscan2
- PLB1 | c.3751G>T p.V1251L | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100577876; called by mutect2, varscan2
- PLEC | c.10255G>C p.E3419Q (on ENST00000322810 / NM_201380.4; = p.E3309Q on NM_000445.5) | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.16); catalogued as COSV100511823; called by muse, mutect2
- PLEKHF1 | c.209A>G p.N70S | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT tolerated (0.64); PolyPhen benign (0.012); catalogued as rs1451114298, COSV101460752; called by muse, mutect2
- PLEKHH1 | c.1781C>T p.T594M | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.633); catalogued as rs188512358; called by mutect2, varscan2
- PLEKHM2 | c.3009G>T p.Q1003H | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99606476; called by muse, mutect2
- PLSCR1 | c.163G>T p.G55C | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.579); catalogued as COSV100678324; called by muse, mutect2
- PLXNA4 | c.4118A>T p.E1373V | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100322996; called by muse, mutect2, varscan2
- POC1A | c.466G>T p.D156Y | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99624032; called by muse, mutect2
- POLQ | c.5661T>A p.D1887E | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.019); catalogued as COSV99951780; called by mutect2, varscan2
- POTEF | c.823C>A p.P275T | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.975); catalogued as COSV100664664; called by muse, mutect2, varscan2
- PPP1R12B | c.1943G>C p.G648A | Missense Mutation (SNP) | VAF 34/157 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99294686; called by muse, mutect2, varscan2
- PPP1R7 | c.161G>T p.R54L | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs140300724, COSV52145980, COSV99297668; called by muse, mutect2, varscan2
- PRDM14 | c.689C>A p.P230Q | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.013); catalogued as rs756135900, COSV99399943; called by muse, mutect2, varscan2
- PRDM14 | c.688C>A p.P230T | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99399949; called by muse, mutect2, varscan2
- PRODH2 | c.1418T>C p.L473P (on ENST00000301175; = p.L397P on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/219 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99995196; called by muse, mutect2, varscan2
- PRSS37 | c.567+2T>A p.X189_splice | Splice Site (SNP) | VAF 9/89 reads (10%) | catalogued as COSV100633883, COSV63339531; called by muse, mutect2
- PSAPL1 | c.508C>T p.P170S | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as rs1378290700, COSV100040365; called by muse, mutect2, varscan2
- PTF1A | c.833G>A p.G278E | Missense Mutation (SNP) | VAF 30/412 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100919571; called by muse, mutect2
- PTPRR | c.852G>T p.K284N | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV99316576; called by muse, mutect2, varscan2
- PUM2 | c.1051G>T p.G351W | Missense Mutation (SNP) | VAF 27/181 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs940395315, COSV100163291; called by muse, mutect2, varscan2
- PXYLP1 | c.1076G>T p.R359L | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV99649274; called by muse, mutect2, varscan2
- RANBP2 | c.7167C>G p.D2389E | Missense Mutation (SNP) | VAF 33/559 reads (6%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.639); catalogued as COSV99311474; called by muse, mutect2
- RAPGEF2 | c.3755G>C p.C1252S | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.317); catalogued as COSV100030703; called by muse, mutect2
- RASA1 | c.1799T>A p.I600N | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV99169651; called by muse, mutect2
- RBM27 | c.1865G>T p.S622I | Missense Mutation (SNP) | VAF 22/182 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as COSV99505811; called by muse, mutect2, varscan2
- RBM45 | c.369C>G p.I123M | Missense Mutation (SNP) | VAF 21/171 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99617545, COSV99617665; called by muse, mutect2, varscan2
- RERGL | c.498C>G p.I166M | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.123); catalogued as COSV57461515, COSV99967809; called by muse, mutect2
- RFC1 | c.2344G>A p.G782S (on ENST00000381897 / NM_001363496.2; = p.G781S on NM_002913.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.057); catalogued as COSV100567345, COSV100567492; called by muse, mutect2, varscan2
- RGS1 | c.308T>A p.L103Q | Missense Mutation (SNP) | VAF 15/194 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100817401; called by muse, mutect2
- RNASET2 | c.344G>T p.W115L | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99218491; called by muse, mutect2, varscan2
- RNF122 | c.434A>G p.Q145R | Missense Mutation (SNP) | VAF 34/203 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.025); catalogued as COSV99823068; called by muse, mutect2, varscan2
- ROBO1 | c.742G>T p.E248* | Nonsense Mutation (SNP) | VAF 5/40 reads (13%) | catalogued as COSV101458354, COSV71394908; called by muse, mutect2
- RP1L1 | c.5500G>A p.G1834S | Missense Mutation (SNP) | VAF 48/326 reads (15%) | SIFT tolerated (0.67); PolyPhen benign (0.208); catalogued as COSV101223021; called by muse, mutect2, varscan2
- RPS6KA5 | c.1693G>A p.D565N | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100002284; called by muse, mutect2, varscan2
- RUBCN | c.2375T>C p.V792A | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.831); catalogued as COSV99583471; called by muse, mutect2, varscan2
- SAMD9L | c.2239G>T p.G747C | Missense Mutation (SNP) | VAF 23/182 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59085831; called by muse, mutect2, varscan2
- SCAF8 | c.3437A>G p.H1146R | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.702); catalogued as COSV100913972; called by muse, mutect2, varscan2
- SEMG2 | c.550G>T p.G184C | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV101033989, COSV65647130; called by muse, mutect2, varscan2
- SERPINB4 | c.1107C>A p.F369L | Missense Mutation (SNP) | VAF 41/222 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100345481, COSV61984887; called by muse, mutect2, varscan2
- SETX | c.6154A>G p.I2052V | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99809026; called by muse, mutect2, varscan2
- SIRPB1 | c.491C>A p.T164K | Missense Mutation (SNP) | VAF 24/151 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.899); catalogued as COSV99498205; called by muse, mutect2, varscan2
- SIRPD | c.5C>T p.P2L | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV101064866; called by muse, mutect2
- SLC12A3 | c.601+2T>A p.X201_splice | Splice Site (SNP) | VAF 5/59 reads (8%) | catalogued as COSV99343900; called by muse, mutect2
- SLC12A5 | c.177G>T p.K59N (on ENST00000454036 / NM_001134771.2; = p.K36N on NM_020708.5) | Missense Mutation (SNP) | VAF 26/158 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV99715522; called by muse, mutect2, varscan2
- SLC22A14 | c.613A>T p.T205S | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99828137; called by muse, mutect2
- SLC27A6 | c.1101C>A p.S367R | Missense Mutation (SNP) | VAF 24/162 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as COSV99322319; called by muse, mutect2, varscan2
- SLC35G2 | c.295T>A p.F99I | Missense Mutation (SNP) | VAF 31/169 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0.027); catalogued as COSV101261984; called by muse, mutect2, varscan2
- SLC45A2 | c.1249C>T p.L417F | Missense Mutation (SNP) | VAF 29/203 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs1361457938, COSV99672431; called by muse, mutect2, varscan2
- SLC8A1 | c.262A>T p.M88L | Missense Mutation (SNP) | VAF 19/153 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0.011); catalogued as COSV100245031, COSV60491753; called by muse, mutect2, varscan2
- SLIT2 | c.3197C>A p.P1066Q | Missense Mutation (SNP) | VAF 26/231 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.714); catalogued as rs768950790, COSV99881793; called by muse, mutect2, varscan2
- SLIT2 | c.3902G>T p.G1301V | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.279); catalogued as COSV99881029; called by muse, mutect2
- SLK | c.805C>G p.L269V | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100211555; called by muse, mutect2, varscan2
- SLX4 | c.3625A>G p.R1209G | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV99567724; called by muse, mutect2, varscan2
- SMC4 | c.2661A>T p.L887F | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100643964; called by muse, mutect2
- SMG1 | c.5500G>A p.E1834K | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV101245365; called by muse, mutect2
- SMG9 | c.739G>C p.E247Q | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99526653; called by muse, mutect2, varscan2
- SNRPC | c.436A>T p.M146L | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.267); catalogued as COSV99765194; called by muse, mutect2
- SNX19 | c.368A>G p.Q123R | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as COSV99772889; called by muse, mutect2, varscan2
- SOS1 | c.3706C>T p.P1236S | Missense Mutation (SNP) | VAF 16/153 reads (10%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.992); catalogued as COSV101216659; called by muse, mutect2, varscan2
- SP100 | c.264G>A p.M88I | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.828); catalogued as COSV99892538; called by muse, mutect2, varscan2
- SP3 | c.157-2A>C p.X53_splice | Splice Site (SNP) | VAF 9/36 reads (25%) | catalogued as rs1334557168, COSV100021665; called by muse, mutect2
- SPAG6 | c.1063G>T p.A355S | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as rs745959953, COSV100510041; called by muse, mutect2, varscan2
- SPEF2 | c.3198T>G p.S1066R | Missense Mutation (SNP) | VAF 9/141 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.109); catalogued as COSV100606582; called by muse, mutect2
- SPHKAP | c.3667C>A p.L1223M | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV100763803; called by muse, mutect2, varscan2
- SPIC | c.266T>G p.I89R | Missense Mutation (SNP) | VAF 12/276 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0.1); catalogued as COSV100162868; called by muse, mutect2
- SPTA1 | c.2689G>T p.A897S | Missense Mutation (SNP) | VAF 46/212 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.309); catalogued as COSV63758160, COSV63759449; called by muse, mutect2, varscan2
- STIL | c.1777C>T p.P593S | Missense Mutation (SNP) | VAF 10/190 reads (5%) | SIFT tolerated (0.65); PolyPhen benign (0.011); catalogued as COSV99680669; called by muse, mutect2
- STX19 | c.656T>C p.L219P | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1029855641, COSV100115240; called by muse, mutect2
- SULF1 | c.260G>T p.C87F | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99482353; called by muse, mutect2, varscan2
- SZT2 | c.7427G>T p.R2476L (on ENST00000634258 / NM_001365999.1; = p.R2419L on NM_015284.4) | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV100986969, COSV65171191; called by muse, mutect2
- TAF3 | c.2232A>T p.K744N | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100719923; called by muse, mutect2
- TBX15 | c.1649G>T p.G550V (on ENST00000369429 / NM_001330677.2; = p.G444V on NM_152380.3) | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV99253737; called by muse, mutect2
- TEKT4 | c.1075G>T p.D359Y | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201902069, COSV54627679, COSV99726214; called by muse, mutect2
- TERT | c.2763G>C p.Q921H | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.176); catalogued as COSV99717025; called by muse, mutect2
- TES | c.258G>T p.M86I | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT tolerated (0.9); PolyPhen benign (0.003); catalogued as COSV100829232; called by muse, mutect2, varscan2
- TGM6 | c.865G>A p.G289R | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99171700; called by muse, mutect2, varscan2
- TIGD5 | c.899C>T p.P300L | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); catalogued as COSV100363970; called by muse, mutect2
- TLN2 | c.3301G>T p.G1101C | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100168287; called by muse, mutect2, varscan2
- TMEM132D | c.3131G>T p.R1044M | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101242601; called by muse, mutect2, varscan2
- TMEM198 | c.244C>T p.R82* | Nonsense Mutation (SNP) | VAF 79/430 reads (18%) | catalogued as COSV54712272; called by muse, mutect2, varscan2
- TMPRSS15 | c.2388G>A p.W796* | Nonsense Mutation (SNP) | VAF 10/162 reads (6%) | catalogued as rs975406724, COSV53050656; called by muse, mutect2
- TNR | c.850G>T p.E284* | Nonsense Mutation (SNP) | VAF 21/80 reads (26%) | catalogued as COSV54888727, COSV99688167; called by muse, mutect2, varscan2
- TNS3 | c.1844G>T p.C615F | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV100235025; called by muse, mutect2, varscan2
- TPM2 | c.463G>C p.A155P | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100253058; called by muse, mutect2, varscan2
- TRAF3 | c.1321T>G p.Y441D | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100693494, COSV61025132; called by muse, mutect2, varscan2
- TRAF3IP3 | c.493G>T p.G165C | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99160393; called by muse, mutect2, varscan2
- TRIM29 | c.1759G>T p.A587S | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.787); catalogued as COSV100531540; called by muse, mutect2, varscan2
- TRIM60 | c.163G>T p.V55F | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.248); catalogued as COSV100593934; called by muse, mutect2, varscan2
- TRPA1 | c.1971G>T p.E657D | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.751); catalogued as COSV100083453; called by muse, mutect2
- TSC22D1 | c.3146del p.P1049Lfs*38 (on ENST00000458659 / NM_183422.4; = p.P120Lfs*38 on NM_006022.4) | Frame Shift Del (DEL) | VAF 6/59 reads (10%) | catalogued as rs762485832; called by mutect2, pindel
- TTN | c.4390G>C p.V1464L (on ENST00000591111; = p.V1418L on NM_003319.4) | Missense Mutation (SNP) | VAF 7/113 reads (6%) | PolyPhen benign (0); catalogued as COSV100599092; called by muse, mutect2
- UBAP2L | c.2596G>T p.G866C | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99670752; called by muse, mutect2, varscan2
- VPS33A | c.1270G>A p.V424I | Missense Mutation (SNP) | VAF 11/143 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.038); catalogued as COSV99931241; called by muse, mutect2
- WDR49 | c.1072G>A p.G358R (on ENST00000308378 / NM_001366158.1; = p.G699R on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as COSV57709774; called by muse, mutect2, varscan2
- WNT16 | c.180C>A p.C60* (on ENST00000222462 / NM_057168.2; = p.C50* on NM_016087.2) | Nonsense Mutation (SNP) | VAF 20/119 reads (17%) | catalogued as COSV99742988; called by muse, mutect2, varscan2
- WWP1 | c.1031G>A p.G344E | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.7); PolyPhen benign (0.15); catalogued as COSV99615847; called by muse, mutect2, varscan2
- XDH | c.3470G>T p.G1157V | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101051934; called by muse, mutect2, varscan2
- XYLT1 | c.955G>T p.E319* | Nonsense Mutation (SNP) | VAF 36/214 reads (17%) | catalogued as COSV99760699; called by muse, mutect2, varscan2
- ZBED9 | c.2219C>A p.S740* | Nonsense Mutation (SNP) | VAF 13/63 reads (21%) | catalogued as COSV101509153; called by muse, mutect2, varscan2
- ZC3H13 | c.4079A>G p.E1360G | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV99667664; called by muse, mutect2, varscan2
- ZFP36 | c.955C>T p.P319S (on ENST00000594442; = p.P313S on NM_003407.5) | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.88); PolyPhen benign (0.012); catalogued as COSV99953691; called by muse, mutect2, varscan2
- ZGLP1 | c.467A>C p.D156A | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100593713; called by muse, mutect2, varscan2
- ZNF106 | c.533A>G p.H178R | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.174); catalogued as rs1420793383, COSV99782294; called by muse, mutect2
- ZNF135 | c.1712T>C p.I571T (on ENST00000313434 / NM_001289401.2; = p.I583T on NM_003436.4) | Missense Mutation (SNP) | VAF 8/179 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.124); catalogued as COSV100536479; called by muse, mutect2
- ZNF224 | c.599G>T p.G200V | Missense Mutation (SNP) | VAF 32/249 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100425325; called by muse, mutect2, varscan2
- ZNF25 | c.98A>G p.Y33C | Missense Mutation (SNP) | VAF 7/137 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100224529; called by muse, mutect2
- ZNF284 | c.1029C>G p.Y343* | Nonsense Mutation (SNP) | VAF 8/124 reads (6%) | catalogued as COSV101398934, COSV101399090, COSV69691707; called by muse, mutect2
- ZNF362 | c.1082C>T p.S361L | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.114); catalogued as rs370622987; called by muse, mutect2, varscan2
- ZNF532 | c.451G>T p.D151Y | Missense Mutation (SNP) | VAF 32/171 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV100266075; called by muse, mutect2, varscan2
- ZNF536 | c.3358G>A p.G1120S | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV100834834; called by muse, mutect2, varscan2
- ZNF549 | c.533C>G p.S178* (on ENST00000376233 / NM_001199295.2; = p.S165* on NM_153263.2) | Nonsense Mutation (SNP) | VAF 6/76 reads (8%) | catalogued as COSV99558395; called by muse, mutect2
- ZNF570 | c.438C>G p.F146L | Missense Mutation (SNP) | VAF 25/233 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV100356061; called by muse, mutect2, varscan2
- ZNF638 | c.1907C>G p.S636C | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1288290489, COSV100038201; called by muse, mutect2
- ZNF800 | c.505C>G p.Q169E | Missense Mutation (SNP) | VAF 13/154 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99757723; called by muse, mutect2
- ZNF804A | c.424G>A p.V142I | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100166773, COSV56462391; called by muse, mutect2
- ZNF804B | c.3529C>A p.H1177N | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV100302349; called by muse, mutect2, varscan2
- ZNF816-ZNF321P | c.263G>T p.G88V | Missense Mutation (SNP) | VAF 41/288 reads (14%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.996); catalogued as COSV100008358; called by muse, mutect2, varscan2
- ZNF835 | c.1270G>A p.G424S | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV73379531; called by muse, mutect2, varscan2
- ZUP1 | c.1503A>T p.K501N | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV100885397; called by muse, mutect2, varscan2
- ADAMTS16 | c.2024-1G>C p.X675_splice | Splice Site (SNP) | VAF 5/96 reads (5%) | called by muse, mutect2
- CDH7 | c.1742_1743insAG p.V582Afs*10 | Frame Shift Ins (INS) | VAF 14/81 reads (17%) | called by mutect2, varscan2
- CHM | c.1101del p.Y368Mfs*41 | Frame Shift Del (DEL) | VAF 7/46 reads (15%) | called by mutect2, pindel, varscan2
- GDF3 | c.284del p.P95Qfs*28 | Frame Shift Del (DEL) | VAF 12/95 reads (13%) | called by mutect2, pindel, varscan2
- HELZ | c.1607_1610del p.L536Yfs*8 | Frame Shift Del (DEL) | VAF 13/86 reads (15%) | called by pindel, varscan2
- IGLV1-50 | c.248T>G p.F83C | Missense Mutation (SNP) | VAF 24/260 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.698); called by muse, mutect2
- KEAP1 | c.1836del p.C613Afs*59 | Frame Shift Del (DEL) | VAF 19/160 reads (12%) | called by mutect2, pindel, varscan2
- KIAA2026 | c.1301G>T p.C434F | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NOC4L | c.621del p.W207* | Frame Shift Del (DEL) | VAF 4/26 reads (15%) | called by mutect2, pindel
- PCLO | c.7103del p.G2368Vfs*76 | Frame Shift Del (DEL) | VAF 10/67 reads (15%) | called by mutect2, pindel, varscan2
- POTEF | c.3116T>A p.V1039E | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); called by mutect2, varscan2
- TECTA | c.6094del p.D2032Ifs*79 | Frame Shift Del (DEL) | VAF 18/138 reads (13%) | called by mutect2, pindel, varscan2
- TRAV21 | c.212C>A p.S71* | Nonsense Mutation (SNP) | VAF 8/46 reads (17%) | called by muse, mutect2
- TRAV21 | c.214A>G p.S72G | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2
- TRMT6 | c.55_72del p.R19_D24del | In Frame Del (DEL) | VAF 11/117 reads (9%) | called by mutect2, pindel
- TTC6 | c.778G>C p.D260H (on ENST00000267368; = p.D1626H on NM_001310135.3) | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.398); called by muse, mutect2
- WASF3 | c.1413del p.N472Mfs*45 | Frame Shift Del (DEL) | VAF 8/71 reads (11%) | called by mutect2, pindel, varscan2
- ZMYM2 | c.737del p.P246Hfs*3 | Frame Shift Del (DEL) | VAF 21/165 reads (13%) | called by mutect2, pindel, varscan2
- ZYG11B | c.286G>T p.V96F | Missense Mutation (SNP) | VAF 7/126 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.505); called by muse, mutect2
- ABCB1 | c.3138C>A p.T1046= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as COSV99712385; called by muse, mutect2, varscan2
- ADAM22 | c.465C>T p.H155= | Silent (SNP) | VAF 11/77 reads (14%) | catalogued as rs370938099; called by muse, mutect2, varscan2
- AGPAT3 | c.462C>T p.T154= | Silent (SNP) | VAF 19/106 reads (18%) | catalogued as rs143039422; called by muse, mutect2, varscan2
- AMER1 | c.2433C>A p.I811= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as COSV100365541, COSV57671158; called by muse, mutect2, varscan2
- APBB1 | c.76C>T p.L26= | Silent (SNP) | VAF 28/154 reads (18%) | catalogued as COSV100193705; called by muse, mutect2, varscan2
- ARNT2 | c.558G>A p.Q186= | Silent (SNP) | VAF 7/146 reads (5%) | catalogued as rs1032993070, COSV100308693; called by muse, mutect2
- ATF2 | c.516C>T p.P172= | Silent (SNP) | VAF 32/189 reads (17%) | catalogued as COSV99908463; called by muse, mutect2, varscan2
- ATP9B | c.1620A>T p.R540= | Silent (SNP) | VAF 12/87 reads (14%) | catalogued as COSV100303064; called by muse, mutect2, varscan2
- B3GNTL1 | c.174T>C p.S58= | Silent (SNP) | VAF 15/108 reads (14%) | catalogued as rs1178109142, COSV100301760; called by muse, mutect2, varscan2
- BFSP1 | c.1587G>A p.Q529= | Silent (SNP) | VAF 11/124 reads (9%) | catalogued as COSV64901089; called by muse, mutect2
- BRD7 | c.744T>A p.A248= | Silent (SNP) | VAF 21/109 reads (19%) | catalogued as COSV101164748; called by muse, varscan2
- C20orf194 | c.834A>T p.I278= | Silent (SNP) | VAF 82/545 reads (15%) | catalogued as COSV99330382; called by muse, mutect2, varscan2
- C2orf15 | c.186G>C p.G62= | Silent (SNP) | VAF 11/84 reads (13%) | catalogued as COSV100208930; called by muse, mutect2, varscan2
- C4A | c.2625G>A p.L875= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV101418315; called by mutect2, varscan2
- CAD | c.3411G>A p.V1137= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV99254571; called by muse, mutect2
- CARD9 | c.1347C>G p.L449= | Silent (SNP) | VAF 9/116 reads (8%) | catalogued as rs1269314543, COSV100261019; called by muse, mutect2
- CCDC70 | c.63C>T p.S21= | Silent (SNP) | VAF 13/126 reads (10%) | catalogued as rs202091572, COSV99665316; called by muse, mutect2
- CDC45 | c.1617C>T p.H539= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as COSV99596503; called by muse, mutect2, varscan2
- CDH7 | c.1743C>T p.R581= | Silent (SNP) | VAF 14/82 reads (17%) | catalogued as rs557624965, COSV100541625; called by mutect2, varscan2
- CFHR3 | c.954G>A p.V318= | Silent (SNP) | VAF 15/174 reads (9%) | catalogued as rs1430825187, COSV100807453; called by muse, mutect2
- CMPK2 | c.1158G>A p.L386= | Silent (SNP) | VAF 9/92 reads (10%) | catalogued as rs1353218644, COSV99878711; called by muse, mutect2, varscan2
- CNOT1 | c.48G>A p.L16= | Silent (SNP) | VAF 11/95 reads (12%) | catalogued as COSV100408648; called by muse, mutect2, varscan2
- COL22A1 | c.4536C>A p.G1512= | Silent (SNP) | VAF 9/64 reads (14%) | catalogued as COSV100276841; called by muse, mutect2, varscan2
- CUBN | c.9033G>C p.G3011= | Silent (SNP) | VAF 13/110 reads (12%) | catalogued as COSV100912203; called by muse, mutect2, varscan2
- CUX2 | c.2655C>T p.P885= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as rs749351102, COSV99918904; called by muse, mutect2
- CX3CR1 | c.840G>A p.T280= | Silent (SNP) | VAF 30/172 reads (17%) | catalogued as rs777272874, COSV64193237, COSV64194860; called by muse, mutect2, varscan2
- CX3CR1 | c.255C>T p.P85= | Silent (SNP) | VAF 9/152 reads (6%) | catalogued as COSV100843139; called by muse, mutect2
- CYLC1 | c.1449T>A p.S483= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV100254207; called by muse, mutect2, varscan2
- CYLC1 | c.1614C>A p.I538= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as COSV100254211, COSV61411303; called by muse, mutect2, varscan2
- DACH2 | c.1422C>G p.R474= | Silent (SNP) | VAF 7/13 reads (54%) | catalogued as COSV100912690; called by muse, mutect2, varscan2
- DCSTAMP | c.897C>T p.P299= | Silent (SNP) | VAF 16/230 reads (7%) | catalogued as COSV99886190; called by muse, mutect2
- DSG1 | c.2607C>A p.V869= | Silent (SNP) | VAF 37/180 reads (21%) | catalogued as rs371231511, COSV57137110; called by muse, mutect2, varscan2
- ENAM | c.1368C>T p.S456= | Silent (SNP) | VAF 6/69 reads (9%) | catalogued as rs1468325382, COSV101252961; called by muse, mutect2
- ESPNL | c.2742C>T p.A914= | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as COSV100547649; called by muse, mutect2
- FANCA | c.2809C>T p.L937= | Silent (SNP) | VAF 12/155 reads (8%) | catalogued as rs773381553, COSV99981253; called by muse, mutect2
- FAT4 | c.10467C>A p.T3489= | Silent (SNP) | VAF 15/190 reads (8%) | catalogued as COSV100627538; called by muse, mutect2
- FCGR2C | c.822C>T p.I274= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as COSV100912571; called by muse, mutect2
- FCRL1 | c.258C>T p.C86= | Silent (SNP) | VAF 15/118 reads (13%) | catalogued as rs909305458, COSV100839737; called by muse, mutect2, varscan2
- GPR157 | c.843C>T p.L281= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as COSV101072562; called by muse, mutect2
- GPR158 | c.3207T>A p.A1069= | Silent (SNP) | VAF 20/161 reads (12%) | catalogued as COSV100892957; called by muse, mutect2, varscan2
- GRID2 | c.2559G>T p.T853= | Silent (SNP) | VAF 15/100 reads (15%) | catalogued as COSV99938441; called by muse, mutect2, varscan2
- GRM7 | c.2286T>C p.Y762= | Silent (SNP) | VAF 19/131 reads (15%) | catalogued as COSV100735885; called by muse, mutect2, varscan2
- HAS2 | c.1198C>A p.R400= | Silent (SNP) | VAF 28/198 reads (14%) | catalogued as rs148429340, COSV100391527, COSV58265637; called by muse, mutect2, varscan2
- HEPN1 | c.6T>A p.G2= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as COSV100005522; called by muse, mutect2, varscan2
- HIF3A | c.855G>T p.A285= (on ENST00000377670 / NM_152795.4; = p.A216= on NM_022462.4) | Silent (SNP) | VAF 26/160 reads (16%) | catalogued as COSV99355587; called by muse, mutect2, varscan2
- HOXA13 | c.642C>A p.A214= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as rs777016740, COSV99763508; called by muse, mutect2, varscan2
- HRNR | c.7947T>A p.S2649= | Silent (SNP) | VAF 20/140 reads (14%) | catalogued as COSV100913085; called by mutect2, varscan2
- HS6ST1 | c.225G>T p.L75= | Silent (SNP) | VAF 4/52 reads (8%) | called by muse, mutect2
- IER3 | c.261C>T p.L87= | Silent (SNP) | VAF 10/122 reads (8%) | catalogued as COSV99458081; called by muse, mutect2
- IGKV1-27 | c.97C>T p.L33= | Silent (SNP) | VAF 13/129 reads (10%) | catalogued as rs1355562352; called by muse, mutect2, varscan2
- IQGAP3 | c.3648A>G p.L1216= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as rs976550937, COSV100752091; called by muse, mutect2, varscan2
- KCTD15 | c.375G>T p.P125= | Silent (SNP) | VAF 9/99 reads (9%) | catalogued as COSV52291157; called by muse, mutect2
- KLF3 | c.183A>T p.P61= | Silent (SNP) | VAF 9/87 reads (10%) | catalogued as COSV99789667; called by muse, mutect2, varscan2
- KLHL14 | c.1186C>A p.R396= | Silent (SNP) | VAF 24/176 reads (14%) | catalogued as COSV100839083, COSV63831834; called by muse, mutect2, varscan2
- KMT2B | c.5229G>C p.L1743= | Silent (SNP) | VAF 56/440 reads (13%) | catalogued as COSV55856460; called by muse, mutect2, varscan2
- KRT6A | c.333T>C p.G111= | Silent (SNP) | VAF 16/106 reads (15%) | catalogued as COSV100416780; called by muse, mutect2, varscan2
- KRTAP10-7 | c.477C>A p.I159= | Silent (SNP) | VAF 14/137 reads (10%) | catalogued as rs1555928584, COSV100170045; called by muse, mutect2, varscan2
- LAPTM5 | c.57C>T p.I19= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as rs778724561, COSV99612236; called by muse, mutect2, varscan2
- LCE3D | c.42C>A p.P14= | Silent (SNP) | VAF 35/165 reads (21%) | catalogued as COSV100909809, COSV64231403; called by muse, mutect2, varscan2
- LMLN | c.195G>T p.R65= | Silent (SNP) | VAF 9/68 reads (13%) | catalogued as COSV99502136; called by muse, mutect2, varscan2
- LRP1 | c.6387A>T p.T2129= | Silent (SNP) | VAF 7/106 reads (7%) | catalogued as COSV99674894; called by muse, mutect2
- MCM7 | c.243A>T p.V81= | Silent (SNP) | VAF 25/176 reads (14%) | catalogued as rs372198296, COSV100384750; called by muse, mutect2, varscan2
- MRC2 | c.2574C>G p.A858= | Silent (SNP) | VAF 3/36 reads (8%) | catalogued as rs1167401814, COSV100315911; called by muse, mutect2
- MRPS30 | c.408G>C p.A136= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs775071652, COSV101539263; called by muse, mutect2, varscan2
- MYOM2 | c.1110G>C p.L370= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as COSV100036935; called by muse, mutect2, varscan2
- NANOS2 | c.153G>A p.G51= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as COSV100379486; called by muse, mutect2, varscan2
- NEU2 | c.381C>T p.V127= | Silent (SNP) | VAF 11/84 reads (13%) | catalogued as COSV99290483; called by muse, mutect2, varscan2
- NLRP1 | c.1176G>T p.P392= | Silent (SNP) | VAF 28/88 reads (32%) | catalogued as COSV99333245; called by muse, mutect2, varscan2
- OR4C46 | c.423G>C p.L141= | Silent (SNP) | VAF 30/185 reads (16%) | catalogued as COSV100060470; called by muse, mutect2, varscan2
- OR4K5 | c.789C>T p.T263= | Silent (SNP) | VAF 28/387 reads (7%) | catalogued as COSV100262217, COSV60004418; called by muse, mutect2
- OR7A10 | c.198G>T p.L66= | Silent (SNP) | VAF 16/89 reads (18%) | catalogued as COSV99932382; called by muse, mutect2, varscan2
- OR7A17 | c.846C>A p.T282= | Silent (SNP) | VAF 19/92 reads (21%) | catalogued as COSV59414581; called by muse, mutect2, varscan2
- PASD1 | c.171G>C p.V57= | Silent (SNP) | VAF 20/89 reads (22%) | catalogued as COSV100949159; called by muse, mutect2, varscan2
- PTPRD | c.1938C>T p.S646= | Silent (SNP) | VAF 25/179 reads (14%) | catalogued as rs775457219, COSV100643805; called by muse, mutect2, varscan2
- PTPRM | c.3399G>A p.R1133= | Silent (SNP) | VAF 6/76 reads (8%) | catalogued as COSV100155611; called by muse, mutect2
- RAB3GAP1 | c.384G>T p.V128= | Silent (SNP) | VAF 17/129 reads (13%) | catalogued as COSV99920747; called by muse, mutect2, varscan2
- RNF10 | c.1500C>A p.L500= | Silent (SNP) | VAF 4/54 reads (7%) | catalogued as COSV100378507; called by muse, mutect2
- SETBP1 | c.1002G>A p.K334= | Silent (SNP) | VAF 23/112 reads (21%) | catalogued as rs1227434675, COSV99952331; called by muse, mutect2, varscan2
- SEZ6L | c.591C>G p.P197= | Silent (SNP) | VAF 24/137 reads (18%) | catalogued as COSV50675419, COSV99961541; called by muse, mutect2, varscan2
- SF3A1 | c.705C>T p.N235= | Silent (SNP) | VAF 9/75 reads (12%) | catalogued as rs1193128691, COSV99305264; called by muse, mutect2, varscan2
- SIPA1L2 | c.3564C>G p.S1188= | Silent (SNP) | VAF 50/362 reads (14%) | catalogued as COSV53397534, COSV99477444; called by muse, mutect2, varscan2
- SLC18B1 | c.1341A>G p.E447= | Silent (SNP) | VAF 12/142 reads (8%) | catalogued as COSV99259010; called by muse, mutect2
- SLC25A42 | c.6T>A p.G2= | Silent (SNP) | VAF 6/47 reads (13%) | called by muse, mutect2
- SLC6A2 | c.846C>T p.V282= | Silent (SNP) | VAF 14/87 reads (16%) | catalogued as COSV99573467; called by muse, mutect2, varscan2
- SLC9A4 | c.1812G>T p.R604= | Silent (SNP) | VAF 12/90 reads (13%) | catalogued as COSV99762787; called by muse, mutect2, varscan2
- SLCO2A1 | c.1401C>T p.L467= | Silent (SNP) | VAF 23/282 reads (8%) | catalogued as COSV100188732; called by muse, mutect2
- SLFN12 | c.349C>T p.L117= | Silent (SNP) | VAF 6/99 reads (6%) | catalogued as COSV100512950; called by muse, mutect2
- SLITRK4 | c.2184G>A p.E728= | Silent (SNP) | VAF 10/92 reads (11%) | catalogued as COSV100567194; called by muse, mutect2, varscan2
- SMC4 | c.1314C>A p.I438= | Silent (SNP) | VAF 16/91 reads (18%) | catalogued as COSV100643963; called by muse, mutect2, varscan2
- SPHKAP | c.4059G>A p.A1353= | Silent (SNP) | VAF 21/121 reads (17%) | catalogued as rs142178318, COSV60874106; called by muse, mutect2, varscan2
- SSH2 | c.666A>G p.E222= | Silent (SNP) | VAF 30/229 reads (13%) | catalogued as COSV99281588; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.723C>A p.T241= | Silent (SNP) | VAF 26/131 reads (20%) | catalogued as rs767948772, COSV60322540; called by muse, mutect2, varscan2
- SYNE1 | c.20136C>T p.I6712= (on ENST00000367255 / NM_182961.4; = p.I6641= on NM_033071.3) | Silent (SNP) | VAF 23/65 reads (35%) | catalogued as rs761906590, COSV99556111; called by muse, mutect2, varscan2
- TAF4 | c.2325C>T p.I775= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV53342039, COSV99433627; called by muse, mutect2, varscan2
- TBL1Y | c.1380C>T p.F460= | Silent (SNP) | VAF 10/79 reads (13%) | catalogued as COSV100667196; called by muse, mutect2, varscan2
- TLR9 | c.1260G>T p.V420= | Silent (SNP) | VAF 25/153 reads (16%) | catalogued as COSV100645567; called by muse, mutect2, varscan2
- TRPM6 | c.4713C>A p.V1571= | Silent (SNP) | VAF 6/80 reads (8%) | catalogued as COSV100665691, COSV62508189; called by muse, mutect2
- TTBK1 | c.27G>A p.K9= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as rs751441680, COSV52497963; called by muse, mutect2, varscan2
- TTC30A | c.810T>A p.A270= | Silent (SNP) | VAF 45/237 reads (19%) | catalogued as rs773275418, COSV100826152; called by muse, mutect2, varscan2
- UGT3A2 | c.781C>T p.L261= | Silent (SNP) | VAF 15/109 reads (14%) | catalogued as rs1241145675, COSV99236061; called by muse, mutect2, varscan2
- USH2A | c.4545G>A p.T1515= | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as rs1463684062, COSV100230772; called by muse, mutect2, varscan2
- VPS11 | c.24C>T p.L8= (on ENST00000620429; = p.L552= on NM_021729.6 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 17/240 reads (7%) | catalogued as COSV56187841; called by muse, mutect2
- WNT10A | c.429C>T p.H143= | Silent (SNP) | VAF 19/96 reads (20%) | catalogued as rs747642854, COSV51463888; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZNF804B | c.456C>A p.P152= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as COSV60823700; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73847044 G>A | 5'Flank (SNP) | VAF 11/44 reads (25%) | called by muse, mutect2, varscan2
- C8orf31 | n.735T>G | RNA (SNP) | VAF 10/89 reads (11%) | called by muse, mutect2, varscan2
- CACNA1C | c.1481+556G>T | Intron (SNP) | VAF 7/30 reads (23%) | catalogued as COSV100216489; called by muse, mutect2, varscan2
- DCHS2 | n.8245C>A | RNA (SNP) | VAF 12/80 reads (15%) | catalogued as COSV100601314; called by muse, mutect2, varscan2
- ETFB | c.58-279C>G | Intron (SNP) | VAF 22/120 reads (18%) | catalogued as COSV100495549; called by muse, mutect2, varscan2
- H2BP2 | chr1:143876113 C>A | 3'Flank (SNP) | VAF 21/175 reads (12%) | called by muse, mutect2, varscan2
- IL9R | c.29-1425C>G | Intron (SNP) | VAF 27/342 reads (8%) | catalogued as COSV99729412; called by muse, mutect2
- KCNAB1 | c.275+22341G>T | Intron (SNP) | VAF 5/51 reads (10%) | catalogued as COSV101050913; called by muse, mutect2
- OBSCN | c.11659+4857T>A | Intron (SNP) | VAF 29/124 reads (23%) | catalogued as COSV99474628; called by muse, mutect2, varscan2
- OR2W5 | n.356G>C | RNA (SNP) | VAF 8/65 reads (12%) | called by muse, mutect2, varscan2
- RNASET2 | c.446+291G>T | Intron (SNP) | VAF 20/101 reads (20%) | called by muse, mutect2, varscan2
- SUN1 | c.659-1482A>G | Intron (SNP) | VAF 41/228 reads (18%) | catalogued as COSV100568573; called by muse, mutect2, varscan2
